Gene-level copy-number profile of tumor specimen TCGA-DY-A1DE-01A from TCGA case TCGA-DY-A1DE, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 56.1 years (20,504 days).
Specimen TCGA-DY-A1DE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.23140093-9390-4bb1-b1dc-b0f6da9d515e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DY-A1DE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/88536066-6705-4d3b-9956-4ae15761d9ed

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 157; copy number 1: 1,930; copy number 2: 15,527; copy number 3: 23,121; copy number 4: 15,087; copy number 5: 2,310; copy number 6: 849; copy number 7: 245; copy number 8: 199; copy number 9: 53; copy number 10: 68; copy number 13: 97; copy number 25: 128; copy number 39: 47.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-DY-A1DE-01): tumor purity 0.75, ploidy 3.09, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 157 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:68,338,728–68,339,528, 1 gene: AL122013.1.
- chr15:67,063,763–67,195,169, 2 genes (within-gene range 0–3): SMAD3, AC012568.1.
- chr16:6,873,899–6,874,005, 1 gene: RNU6-457P.
- chr17:19,417,769–19,492,991, 1 gene (within-gene range 0–2): AC004448.2.
- chr17:19,457,080–22,706,703, 150 genes (broad region; genes not listed).
- chr18:50,967,991–51,058,144, 2 genes (within-gene range 0–1): ELAC1, AC091551.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 814 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:159,649,151–159,954,237, 19 genes, copy number 8: AL445528.2, CRPP1, CRP, AL445528.1, DUSP23, FCRL6, SLAMF8, AL590560.2, SNHG28, AL590560.1, VSIG8, AL590560.3, CFAP45, MIR4259, AL590560.5, AL590560.4, TAGLN2, IGSF9, SLAMF9.
- chr2:104,853,285–106,544,297, 38 genes, copy number 8 (within-gene range 6–8): AC018730.1, POU3F3, LINC01159, AC010884.1, MRPS9-AS2, MRPS9, MRPS9-AS1, LINC01918, GPR45, AC012360.2, TGFBRAP1, AC012360.1, AC012360.3, C2orf49, FHL2, AC108058.1, AC018802.1, AC018802.2, NCK2, AC010978.1, AC009505.1, ECRG4, UXS1, AC018878.1, AC092106.1, RPL22P10, SRSF3P4, RPS21P2, RPL27AP4, ILRUNP1, AC114755.1, ANAPC1P6, PLGLA, RGPD3, AC097527.1, CD8B2, AC108868.2, AC108868.1.
- chr8:41,261,962–41,309,473, 5 genes, copy number 10: SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P.
- chr19:29,489,775–41,170,166, 477 genes, copy number 8–39 (broad region; genes not listed).
- chr20:18,467,389–32,439,319, 275 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,930. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
